FM case AD3306 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas.
https://portal.gdc.cancer.gov/cases/0a087b9f-b60d-4a38-9b15-d8429ef86319

Male, 76.0 years: Urothelial carcinoma, NOS (ICD-O-3 8120/3); specimen biopsied or resected from the lung. Sample type: Tumor.
